Somatic mutation profile of tumor specimen TARGET-10-PATNAM-09A (aliquot TARGET-10-PATNAM-09A-01D) from TARGET case TARGET-10-PATNAM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (814 days).
Specimen TARGET-10-PATNAM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87b84798-1457-4528-b1f0-d3e295744ee5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATNAM-10A (Blood Derived Normal), aliquot TARGET-10-PATNAM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e5e53f-d5cd-4c15-8725-bf922c458fb5

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Splice Region 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRN | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302480844, COSV50007330; called by muse, mutect2, varscan2
- DHX30 | c.3192-4del | Splice Region (DEL) | VAF 59/140 reads (42%) | called by mutect2, pindel, varscan2
- HKDC1 | c.1560G>A p.P520= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs766012049, COSV63575550, COSV63577752; called by muse, mutect2, varscan2
- RIMBP2 | c.1923G>A p.P641= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs565981416, COSV55474314; called by muse, varscan2
- KLK7 | c.*115C>A | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
